Somatic mutation profile of tumor specimen TARGET-20-PATCYY-04A (aliquot TARGET-20-PATCYY-04A-01D) from TARGET case TARGET-20-PATCYY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,388 days).
Specimen TARGET-20-PATCYY-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 662a5a55-09e8-4022-91a0-f4aeb08aaee8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATCYY-14A (Bone Marrow Normal), aliquot TARGET-20-PATCYY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42aee188-1031-43a1-94d8-5aefba27ecf1

The open-access MAF lists 14 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, 3'UTR 4, Missense Mutation 3, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDR | c.1444T>C p.C482R | Missense Mutation (SNP) | VAF 30/229 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34231037, CM087498, COSV55778415; ClinVar: risk factor / likely benign; called by muse, mutect2
- AHNAK2 | c.10208A>G p.K3403R | Missense Mutation (SNP) | VAF 57/307 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as rs373024852; called by muse, mutect2, varscan2
- DOCK8 | c.3840G>A p.L1280= | Splice Region (SNP) | VAF 29/182 reads (16%) | catalogued as rs1001055970; called by muse, mutect2, varscan2
- KCNH4 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs749177652, COSV99238072; called by muse, mutect2, varscan2
- CCDC168 | c.17943G>A p.E5981= | Silent (SNP) | VAF 50/295 reads (17%) | catalogued as rs947019748, COSV59420926; called by muse, mutect2, varscan2
- CCDC168 | c.4062A>G p.T1354= | Silent (SNP) | VAF 41/269 reads (15%) | catalogued as rs775964015; called by muse, mutect2, varscan2
- COL6A2 | c.291C>T p.G97= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs1007921670, COSV55999679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATA3 | c.840A>G p.G280= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs747504372; called by muse, mutect2, varscan2
- PCLO | c.9468A>G p.V3156= | Silent (SNP) | VAF 49/231 reads (21%) | catalogued as rs182878395; called by muse, mutect2, varscan2
- IL18BP | chr11:72002844 C>T | 3'Flank (SNP) | VAF 27/139 reads (19%) | catalogued as rs1269752418; called by muse, mutect2, varscan2
- MLLT6 | c.*2993C>T | 3'UTR (SNP) | VAF 14/90 reads (16%) | catalogued as rs374954378; called by mutect2, varscan2
- PPP2R3B | c.*242_*247delinsCAGCAT | 3'UTR (ONP) | VAF 7/40 reads (18%) | called by mutect2*, pindel
- RUNX1T1 | c.*4209A>G | 3'UTR (SNP) | VAF 23/182 reads (13%) | catalogued as rs1008985555; called by muse, mutect2, varscan2
- SIN3A | c.*350G>A | 3'UTR (SNP) | VAF 28/214 reads (13%) | called by muse, mutect2, varscan2
